Somatic mutation profile of tumor specimen TCGA-OR-A5LB-01A (aliquot TCGA-OR-A5LB-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LB, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 59.0 years (21,565 days).
Specimen TCGA-OR-A5LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e4430d1-b512-4a8d-a974-78c8cc066004.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LB-10A (Blood Derived Normal), aliquot TCGA-OR-A5LB-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48be741f-1214-4471-9625-d79480dec544

The open-access MAF lists 244 somatic variants for this specimen: 192 protein-altering or splice-affecting, 47 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 47, Frame Shift Del 37, Frame Shift Ins 16, In Frame Del 12, Nonsense Mutation 10, RNA 4, Splice Site 3, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 38/142 reads (27%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CHEK2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 45/47 reads (96%) | catalogued as rs587781269, CM110734, COSV60421481; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5098C>T p.R1700* | Nonsense Mutation (SNP) | VAF 26/191 reads (14%) | catalogued as rs587784137, CM074953; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 72/83 reads (87%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.537); catalogued as rs767071679, COSV50138819; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as rs757016425; called by mutect2, varscan2
- ACSL1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1177836658; called by muse, mutect2, varscan2
- AKAP8 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs140271912, COSV54102874; called by muse, mutect2, varscan2
- ANKFN1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100593019; called by muse, mutect2
- AP1G2 | c.1628+2_1628+5del p.X543_splice | Splice Site (DEL) | VAF 133/282 reads (47%) | catalogued as rs766645158; called by mutect2, varscan2
- ATP2A1 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs200092983, COSV63921560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT4 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 98/111 reads (88%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.448); catalogued as rs750901657; called by muse, mutect2, varscan2
- BCL7C | c.203_204del p.R68Ifs*25 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs747562410; called by pindel, varscan2
- BDKRB2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs200693201, COSV60014290; called by muse, mutect2, varscan2
- BRD3 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs200965087; called by muse, varscan2
- BTNL2 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 143/164 reads (87%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs760675404, COSV66630953; called by muse, varscan2
- C1D | c.359dup p.N120Kfs*17 | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | catalogued as rs776000138; called by mutect2, pindel, varscan2
- CARMIL3 | c.4003C>T p.R1335W | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs768605232; called by muse, mutect2, varscan2
- CARNMT1 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs763232819; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 11/22 reads (50%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC186 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs201374071, COSV65161653; called by muse, mutect2, varscan2
- CDK5RAP2 | c.998del p.K333Rfs*76 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | catalogued as rs973156155; called by mutect2, pindel, varscan2
- CHAF1A | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs751874513; called by muse, mutect2, varscan2
- CLTB | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs372564708; called by muse, mutect2, varscan2
- COL20A1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.336); catalogued as rs1321421322; called by muse, mutect2, varscan2
- COX6B1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs745734530, COSV55838226; called by muse, mutect2, varscan2
- CYP4A22 | c.1207C>G p.R403G | Missense Mutation (SNP) | VAF 162/182 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV53740981; called by muse, mutect2, varscan2
- DDX47 | c.426dup p.P143Tfs*13 | Frame Shift Ins (INS) | VAF 19/53 reads (36%) | catalogued as rs769535432; called by mutect2, varscan2
- DNAJA3 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 116/127 reads (91%) | SIFT tolerated (0.24); PolyPhen benign (0.406); catalogued as rs766881681; called by muse, varscan2
- DOCK9 | c.4002dup p.T1335Yfs*4 (on ENST00000376460 / NM_001366676.2; = p.T1336Yfs*4 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 87/249 reads (35%) | catalogued as rs1344550381; called by mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 59/94 reads (63%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- ERCC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750132739; called by muse, mutect2, varscan2
- FAT4 | c.7629del p.D2544Mfs*13 | Frame Shift Del (DEL) | VAF 99/264 reads (38%) | catalogued as COSV100629863; called by mutect2, pindel, varscan2
- FAXC | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 72/78 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.237); catalogued as COSV67604406; called by muse, varscan2
- FBH1 | c.503A>G p.D168G (on ENST00000362091 / NM_178150.3; = p.D219G on NM_032807.4) | Missense Mutation (SNP) | VAF 87/424 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs762146468; called by muse, mutect2, varscan2
- FBN3 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs370751618; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 48/56 reads (86%) | catalogued as rs756304971; called by mutect2, varscan2
- HCFC1 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 138/152 reads (91%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV100128946; called by muse, mutect2, varscan2
- HOXB13 | c.72del p.R25Gfs*9 | Frame Shift Del (DEL) | VAF 92/144 reads (64%) | catalogued as COSV51707080; called by mutect2, pindel, varscan2
- HPCAL4 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 204/220 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs532685057, COSV65716234; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/278 reads (15%) | catalogued as rs750779916, COSV60737300; called by mutect2, varscan2
- IGHG4 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 225/705 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as rs375787463; called by muse, mutect2, varscan2
- IGSF3 | c.2141C>T p.A714V (on ENST00000369486 / NM_001007237.3; = p.A734V on NM_001542.4) | Missense Mutation (SNP) | VAF 200/215 reads (93%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs1367332633, COSV59590754; called by muse, mutect2, varscan2
- IQGAP3 | c.4619C>T p.A1540V | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs764657941; called by muse, mutect2, varscan2
- KCNC4 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966007199; called by muse, mutect2, varscan2
- KCNT1 | c.1913C>T p.P638L (on ENST00000488444; = p.P657L on NM_020822.3) | Missense Mutation (SNP) | VAF 128/234 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs566157365, COSV53696323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF7 | c.1640dup p.R549Afs*40 | Frame Shift Ins (INS) | VAF 37/108 reads (34%) | catalogued as rs770571299; called by mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- LPCAT4 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 44/84 reads (52%) | catalogued as COSV100149049; called by muse, mutect2, varscan2
- LRP1 | c.6712G>A p.A2238T | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV54503690; called by muse, varscan2
- LVRN | c.1390del p.S464Lfs*15 | Frame Shift Del (DEL) | VAF 82/207 reads (40%) | catalogued as rs756702147; called by mutect2, pindel, varscan2
- MAGEC1 | c.1358A>G p.Y453C | Missense Mutation (SNP) | VAF 76/77 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53568085; called by muse, mutect2, varscan2
- MAP3K14 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160658832; called by muse, mutect2, varscan2
- MAP3K19 | c.3583A>G p.M1195V | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1339848808; called by muse, mutect2, varscan2
- MCC | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs767237776, COSV68728766; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 24/205 reads (12%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MIB2 | c.2518del p.D840Tfs*22 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | catalogued as rs747046371; called by mutect2, varscan2
- MLH1 | c.213_215del p.E71del | In Frame Del (DEL) | VAF 42/51 reads (82%) | catalogued as rs63751642; called by pindel, varscan2
- MYH6 | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs369247906; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- NELFA | c.419G>A p.G140D (on ENST00000542778; = p.G129D on NM_005663.5) | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs762339956; called by muse, mutect2, varscan2
- NKPD1 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1299730422, COSV55522922; called by muse, mutect2, varscan2
- NR2E3 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755224888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUFIP1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 92/107 reads (86%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs750178878; called by muse, mutect2, varscan2
- ORMDL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs781542210; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- PARP12 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441758501, COSV54933162; called by muse, mutect2, varscan2
- PBXIP1 | c.2113_2115del p.K705del | In Frame Del (DEL) | VAF 52/74 reads (70%) | catalogued as rs1558036439; called by pindel, varscan2
- PHACTR2 | c.685dup p.T229Nfs*5 | Frame Shift Ins (INS) | VAF 17/22 reads (77%) | catalogued as rs746858891; called by mutect2, varscan2
- PHACTR3 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV63026244; called by muse, mutect2
- PLXNB2 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 69/81 reads (85%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1157753906; called by muse, mutect2, varscan2
- PPP1R3A | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV52877979; called by muse, mutect2, varscan2
- PRX | c.3568G>A p.V1190M | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1460400178; called by muse, mutect2, varscan2
- RAB40B | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1216041504; called by muse, mutect2, varscan2
- REM2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57465384; called by muse, mutect2
- RNF141 | c.460_462del p.E154del | In Frame Del (DEL) | VAF 30/38 reads (79%) | catalogued as rs1334042364; called by pindel, varscan2
- RPA4 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV61263930; called by muse, mutect2, varscan2
- RPL22 | c.279_281del p.K93del | In Frame Del (DEL) | VAF 144/212 reads (68%) | catalogued as rs1324812542; called by pindel, varscan2
- RPTOR | c.3574G>A p.V1192I | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); catalogued as rs375708825, COSV60808480; called by muse, mutect2, varscan2
- RYR1 | c.1007del p.P336Lfs*54 | Frame Shift Del (DEL) | VAF 131/349 reads (38%) | catalogued as COSV62094961; called by mutect2, pindel, varscan2
- SFMBT2 | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62816167; called by muse, mutect2, varscan2
- SLC10A2 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201168803; called by muse, mutect2
- SLC15A1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780275601, COSV64734137; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 40/44 reads (91%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC39A6 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 194/222 reads (87%) | catalogued as rs753468777; called by muse, mutect2, varscan2
- SLC5A5 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1421225800; called by muse, varscan2
- SLITRK1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 83/101 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100999824, COSV101000073; called by muse, mutect2, varscan2
- SMC1A | c.1142_1144del p.E381del | In Frame Del (DEL) | VAF 97/109 reads (89%) | catalogued as rs797045991; called by pindel, varscan2
- SMTNL2 | c.735_737del p.K245del (on ENST00000389313 / NM_001114974.2; = p.K101del on NM_198501.3) | In Frame Del (DEL) | VAF 16/63 reads (25%) | catalogued as rs772763150; called by pindel, varscan2
- SPATA9 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV57223454; called by muse, mutect2, varscan2
- SPRR2G | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 65/71 reads (92%) | PolyPhen possibly damaging (0.624); catalogued as rs573005165; called by muse, mutect2, varscan2
- ST18 | c.1862del p.N621Ifs*10 | Frame Shift Del (DEL) | VAF 121/143 reads (85%) | catalogued as rs1563701552; called by mutect2, varscan2
- TENM2 | c.6772G>A p.G2258R (on ENST00000518659 / NM_001122679.2; = p.G2019R on NM_001080428.3) | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265081367, COSV101319190; called by muse, mutect2, varscan2
- TIAM1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs202148756; called by muse, mutect2, varscan2
- TMEM203 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 156/521 reads (30%) | catalogued as COSV100411273; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 46/105 reads (44%) | catalogued as rs749773249; called by mutect2, varscan2
- TNS3 | c.2358del p.Q787Sfs*33 | Frame Shift Del (DEL) | VAF 71/148 reads (48%) | catalogued as COSV60787512; called by mutect2, varscan2
- VAV1 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369256102; called by muse, varscan2
- WDR59 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs1248018071, COSV100049780; called by muse, mutect2, varscan2
- XIRP1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs751589146; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 112/202 reads (55%) | catalogued as rs762052135; called by mutect2, varscan2
- ZBTB40 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 129/140 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs780012881, COSV100988897; called by muse, mutect2
- ZNF330 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 147/301 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV53707437; called by muse, mutect2, varscan2
- ZNF384 | c.574del p.R192Gfs*16 | Frame Shift Del (DEL) | VAF 21/175 reads (12%) | catalogued as COSV60533454; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF529 | c.1154A>C p.Q385P | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV61899292; called by muse, mutect2, varscan2
- ZPBP | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs200921057, COSV50422247, COSV50424315; called by muse, mutect2, varscan2
- ABHD3 | c.596A>C p.E199A | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ADAMTS13 | c.1643G>A p.C548Y | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRE2 | c.2332T>C p.Y778H | Missense Mutation (SNP) | VAF 79/417 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ADGRE5 | c.1580G>A p.C527Y (on ENST00000242786 / NM_078481.4; = p.C434Y on NM_001784.5) | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADNP2 | c.435_436del p.K146Ifs*3 | Frame Shift Del (DEL) | VAF 81/99 reads (82%) | called by mutect2, pindel, varscan2
- ADSS1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 82/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALDH1L2 | c.1304A>T p.N435I | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, mutect2
- ANK2 | c.6985G>A p.G2329S | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANXA2R | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 110/200 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AP1AR | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ATP7B | c.1094_1095dup p.A366Lfs*4 | Frame Shift Ins (INS) | VAF 100/113 reads (88%) | called by mutect2, varscan2
- CABLES2 | c.1416G>T p.R472S | Missense Mutation (SNP) | VAF 114/218 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CACNB3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN6 | c.166-2A>G p.X56_splice | Splice Site (SNP) | VAF 73/133 reads (55%) | called by muse, mutect2, varscan2
- CCDC77 | c.559A>C p.S187R | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL6A5 | c.6473del p.L2158Yfs*25 (on ENST00000312481; = p.L2154Yfs*25 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- CRELD2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 88/94 reads (94%) | SIFT tolerated (0.29); PolyPhen benign (0.105); called by muse, mutect2
- CWC27 | c.864dup p.L289Ifs*10 | Frame Shift Ins (INS) | VAF 30/74 reads (41%) | called by mutect2, pindel, varscan2
- DAXX | c.1176_1180del p.R394Sfs*22 | Frame Shift Del (DEL) | VAF 55/64 reads (86%) | called by mutect2, pindel, varscan2
- DKC1 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- EGR2 | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHB3 | c.2989C>A p.Q997K | Missense Mutation (SNP) | VAF 97/113 reads (86%) | SIFT tolerated (0.1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- EXPH5 | c.2357_2358dup p.D787Qfs*48 | Frame Shift Ins (INS) | VAF 49/77 reads (64%) | called by mutect2, pindel, varscan2
- FAM43A | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 286/325 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- FBN2 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FBXO27 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- FBXO34 | c.1454del p.L485Cfs*13 | Frame Shift Del (DEL) | VAF 75/168 reads (45%) | called by mutect2, varscan2
- GOLGA2 | c.1510del p.E504Sfs*42 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- GPR68 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 186/379 reads (49%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIN1 | c.1445G>A p.G482D | Missense Mutation (SNP) | VAF 93/614 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GRIN2D | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 121/277 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GTF2IRD1 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HEATR9 | c.349A>T p.I117F | Missense Mutation (SNP) | VAF 195/218 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HERC6 | c.501dup p.S168Lfs*41 | Frame Shift Ins (INS) | VAF 61/154 reads (40%) | called by mutect2, pindel, varscan2
- HK2 | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by mutect2, varscan2
- HNRNPH2 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 310/335 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- HOXC4 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 178/395 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IDI1 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- IGHV3-33 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KCNT1 | c.2295C>T p.G765= (on ENST00000488444; = p.G784= on NM_020822.3) | Splice Region (SNP) | VAF 40/454 reads (9%) | called by muse, mutect2
- KIAA1210 | c.5120T>A p.I1707N | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KIF3B | c.1789dup p.S597Kfs*2 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- KLHDC9 | c.56_57del p.P19Rfs*9 | Frame Shift Del (DEL) | VAF 86/127 reads (68%) | called by mutect2, pindel, varscan2
- LETMD1 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 170/372 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LIPE | c.965_967del p.F322del | In Frame Del (DEL) | VAF 61/73 reads (84%) | called by pindel, varscan2
- MIA3 | c.2977dup p.M993Nfs*3 | Frame Shift Ins (INS) | VAF 81/129 reads (63%) | called by mutect2, pindel, varscan2
- MPHOSPH9 | c.3354dup p.D1119* | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- MPP3 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYOCD | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 83/87 reads (95%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NLGN2 | c.1038C>T p.R346= | Splice Region (SNP) | VAF 12/219 reads (5%) | called by muse, mutect2
- NOP56 | c.1250A>T p.N417I | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NR5A1 | c.1123_1125del p.I375del | In Frame Del (DEL) | VAF 85/194 reads (44%) | called by pindel, varscan2
- NUP155 | c.974_975del p.S325Cfs*4 (on ENST00000231498 / NM_153485.3; = p.S266Cfs*4 on NM_004298.4) | Frame Shift Del (DEL) | VAF 250/705 reads (35%) | called by pindel, varscan2
- NYNRIN | c.4306_4307del p.L1436Vfs*49 | Frame Shift Del (DEL) | VAF 62/132 reads (47%) | called by pindel, varscan2
- PCDH15 | c.28T>G p.C10G | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PCTP | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 133/147 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PDZRN3 | c.2929_2931del p.E977del | In Frame Del (DEL) | VAF 66/78 reads (85%) | called by pindel, varscan2
- PIAS2 | c.449del p.N150Ifs*17 | Frame Shift Del (DEL) | VAF 215/323 reads (67%) | called by mutect2, pindel, varscan2
- PML | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 54/126 reads (43%) | called by muse, varscan2
- RASGEF1C | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 60/356 reads (17%) | called by muse, mutect2, varscan2
- RASGRP1 | c.2045G>A p.G682D | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SECISBP2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD5 | c.3547A>T p.K1183* | Nonsense Mutation (SNP) | VAF 81/97 reads (84%) | called by muse, mutect2, varscan2
- SLC6A11 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 10/283 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- SLFN12 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 56/69 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMG1 | c.4699_4702del p.T1567* | Frame Shift Del (DEL) | VAF 68/186 reads (37%) | called by pindel, varscan2
- SPRED1 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- STAC | c.1040_1042del p.K347del | In Frame Del (DEL) | VAF 62/68 reads (91%) | called by pindel, varscan2
- SYNE1 | c.4727C>T p.A1576V (on ENST00000367255 / NM_182961.4; = p.A1583V on NM_033071.3) | Missense Mutation (SNP) | VAF 102/111 reads (92%) | SIFT tolerated (0.28); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SYNE2 | c.14139+2T>C p.X4713_splice | Splice Site (SNP) | VAF 84/204 reads (41%) | called by muse, mutect2, varscan2
- TAF3 | c.2530G>A p.V844M | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TLR6 | c.160del p.T54Pfs*4 | Frame Shift Del (DEL) | VAF 70/144 reads (49%) | called by mutect2, varscan2
- TMEM130 | c.743dup p.L248Ffs*33 | Frame Shift Ins (INS) | VAF 34/242 reads (14%) | called by mutect2, pindel, varscan2
- TMEM161A | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TOP1 | c.552dup p.V185Sfs*3 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- TRIL | c.1181del p.P394Rfs*30 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- TRIM21 | c.560dup p.N187Kfs*5 | Frame Shift Ins (INS) | VAF 19/26 reads (73%) | called by mutect2, varscan2
- TYRP1 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- UBR5 | c.5285C>A p.A1762D | Missense Mutation (SNP) | VAF 112/125 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UNC5C | c.1471del p.Q491Kfs*15 | Frame Shift Del (DEL) | VAF 190/471 reads (40%) | called by mutect2, pindel, varscan2
- VWA3A | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WASHC3 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WDR72 | c.2332del p.M778Cfs*9 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- ZNF211 | c.1490_1492del p.I497del (on ENST00000347302 / NM_198855.4; = p.I510del on NM_006385.5) | In Frame Del (DEL) | VAF 92/188 reads (49%) | called by mutect2, pindel, varscan2
- ZNF25 | c.716_718del p.F239del | In Frame Del (DEL) | VAF 66/172 reads (38%) | called by pindel, varscan2
- ZNF831 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNRF3 | c.1179del p.V394Sfs*4 (on ENST00000544604 / NM_001206998.2; = p.V294Sfs*4 on NM_032173.3) | Frame Shift Del (DEL) | VAF 128/187 reads (68%) | called by mutect2, pindel, varscan2
- ABCA13 | c.2394C>T p.N798= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs748153272, COSV70025728; called by muse, mutect2, varscan2
- ADGRL1 | c.1482G>A p.Q494= (on ENST00000340736 / NM_001008701.3; = p.Q489= on NM_014921.5) | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs1469192286; called by muse, mutect2, varscan2
- AGXT2 | c.1452G>A p.A484= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs372814383; called by muse, mutect2
- APBA2 | c.1512C>T p.F504= | Silent (SNP) | VAF 120/285 reads (42%) | catalogued as rs781368703, COSV67104221; called by muse, mutect2, varscan2
- APOBR | c.2976C>T p.R992= (on ENST00000431282; = p.R1001= on NM_018690.4) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs186642005; called by muse, mutect2, varscan2
- BOLA1 | c.333C>T p.P111= | Silent (SNP) | VAF 99/108 reads (92%) | catalogued as rs587688660; called by muse, mutect2, varscan2
- CACNA1B | c.6417G>A p.P2139= | Silent (SNP) | VAF 70/188 reads (37%) | catalogued as rs763000710; called by muse, varscan2
- CADM1 | c.153C>T p.D51= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs138296059; called by muse, mutect2, varscan2
- CAPG | c.453C>T p.T151= | Silent (SNP) | VAF 151/171 reads (88%) | catalogued as rs769755908; called by muse, mutect2, varscan2
- CCS | c.81C>T p.D27= | Silent (SNP) | VAF 84/92 reads (91%) | catalogued as rs543925670; called by muse, mutect2, varscan2
- CCT8L2 | c.558C>T p.H186= | Silent (SNP) | VAF 149/162 reads (92%) | catalogued as rs771570475, COSV63462326; called by muse, varscan2
- CDX4 | c.102C>T p.G34= | Silent (SNP) | VAF 87/96 reads (91%) | catalogued as COSV65171920; called by muse, varscan2
- CEMIP | c.2376C>T p.H792= | Silent (SNP) | VAF 140/149 reads (94%) | catalogued as rs372531428; called by muse, mutect2, varscan2
- CPA1 | c.198A>G p.R66= | Silent (SNP) | VAF 111/257 reads (43%) | called by muse, mutect2, varscan2
- CUX2 | c.2796C>T p.S932= | Silent (SNP) | VAF 154/279 reads (55%) | catalogued as rs747433827, COSV55632017; called by muse, mutect2, varscan2
- DYNC2I1 | c.3078G>A p.A1026= | Silent (SNP) | VAF 84/194 reads (43%) | catalogued as rs374045806; called by muse, mutect2, varscan2
- ERGIC1 | c.66G>A p.T22= | Silent (SNP) | VAF 122/319 reads (38%) | catalogued as rs760955420, COSV67128975; called by muse, mutect2, varscan2
- EXOC4 | c.246C>T p.R82= | Silent (SNP) | VAF 136/334 reads (41%) | called by muse, mutect2, varscan2
- FCN2 | c.306G>A p.P102= | Silent (SNP) | VAF 92/167 reads (55%) | catalogued as rs369807019, COSV52477223; called by muse, mutect2, varscan2
- FHOD3 | c.1848C>T p.N616= (on ENST00000359247 / NM_001281739.3; = p.N633= on NM_025135.5) | Silent (SNP) | VAF 176/202 reads (87%) | catalogued as rs141915411; called by muse, varscan2
- FUT6 | c.708G>A p.T236= | Silent (SNP) | VAF 264/589 reads (45%) | catalogued as rs141754965; called by muse, mutect2, varscan2
- GBF1 | c.4245C>T p.C1415= (on ENST00000369983 / NM_001377137.1; = p.C1414= on NM_004193.3) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs139000128; called by muse, mutect2, varscan2
- GPC4 | c.1365C>T p.S455= | Silent (SNP) | VAF 115/126 reads (91%) | catalogued as rs1432842684; called by muse, mutect2, varscan2
- GRHL1 | c.1071C>T p.N357= | Silent (SNP) | VAF 61/67 reads (91%) | catalogued as rs746451999, COSV61406648, COSV61407434; called by muse, mutect2, varscan2
- GSC | c.435G>A p.S145= | Silent (SNP) | VAF 78/306 reads (25%) | called by muse, mutect2, varscan2
- HPS5 | c.3123G>A p.T1041= (on ENST00000349215 / NM_181507.2; = p.T927= on NM_007216.4) | Silent (SNP) | VAF 65/71 reads (92%) | catalogued as rs558229020; called by muse, mutect2, varscan2
- ICAM1 | c.618C>A p.P206= | Silent (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- KLHL31 | c.615G>T p.S205= | Silent (SNP) | VAF 44/52 reads (85%) | called by muse, mutect2, varscan2
- LOXL3 | c.81G>A p.P27= | Silent (SNP) | VAF 16/169 reads (9%) | catalogued as rs376297326; called by muse, mutect2
- MAGOHB | c.24C>T p.Y8= | Silent (SNP) | VAF 95/229 reads (41%) | catalogued as rs748618251; called by muse, mutect2, varscan2
- MORN1 | c.453C>T p.N151= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs772157368; called by muse, mutect2, varscan2
- MYO7A | c.3594C>T p.C1198= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as rs782694195, CM112902, COSV101289295; called by muse, mutect2
- NELFCD | c.1386G>A p.A462= (on ENST00000602795; = p.A444= on NM_198976.4) | Silent (SNP) | VAF 139/586 reads (24%) | catalogued as rs141996345; called by muse, mutect2, varscan2
- NPHP1 | c.18G>A p.Q6= | Silent (SNP) | VAF 56/162 reads (35%) | called by muse, varscan2
- PEX5 | c.945T>G p.L315= (on ENST00000420616; = p.L307= on NM_000319.5) | Silent (SNP) | VAF 129/226 reads (57%) | called by muse, mutect2, varscan2
- PLXNB2 | c.2223C>T p.Y741= | Silent (SNP) | VAF 60/65 reads (92%) | catalogued as rs758070664; called by muse, mutect2, varscan2
- PMS2 | c.1629C>T p.D543= | Silent (SNP) | VAF 66/138 reads (48%) | catalogued as rs111673299; ClinVar: likely benign / benign; called by muse, varscan2
- PPP1R26 | c.1095C>T p.D365= | Silent (SNP) | VAF 149/306 reads (49%) | catalogued as rs138779417; called by muse, mutect2, varscan2
- RASSF4 | c.600G>A p.L200= | Silent (SNP) | VAF 135/275 reads (49%) | called by muse, mutect2, varscan2
- RYR1 | c.10734C>T p.G3578= | Silent (SNP) | VAF 167/320 reads (52%) | catalogued as COSV100617035; called by muse, mutect2, varscan2
- SLC2A13 | c.810A>T p.G270= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- SLC40A1 | c.660C>T p.Y220= | Silent (SNP) | VAF 98/119 reads (82%) | catalogued as rs368843037, COSV53724060; called by muse, mutect2, varscan2
- STIM2 | c.585G>A p.Q195= | Silent (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- TDRD5 | c.2034C>T p.Y678= | Silent (SNP) | VAF 120/133 reads (90%) | called by muse, mutect2, varscan2
- TNR | c.552G>A p.E184= | Silent (SNP) | VAF 145/171 reads (85%) | catalogued as COSV54901093; called by muse, varscan2
- VWF | c.429C>T p.S143= | Silent (SNP) | VAF 153/295 reads (52%) | catalogued as rs202062122; called by muse, mutect2, varscan2
- ZNF160 | c.243G>A p.T81= | Silent (SNP) | VAF 74/158 reads (47%) | catalogued as rs374134545; called by muse, mutect2, varscan2
- HMGB1P1 | n.190G>T | RNA (SNP) | VAF 38/82 reads (46%) | called by muse, varscan2
- LINC01559 | n.549C>A | RNA (SNP) | VAF 59/141 reads (42%) | called by muse, mutect2, varscan2
- MIR298 | n.67C>A | RNA (SNP) | VAF 144/321 reads (45%) | called by muse, mutect2, varscan2
- PKD1L2 | n.287C>T | RNA (SNP) | VAF 46/113 reads (41%) | catalogued as rs531025677; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+299del | Intron (DEL) | VAF 15/34 reads (44%) | called by mutect2, varscan2
